MMRF case MMRF_1148 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/7ea322bb-7ce9-4ba4-97b4-d23b140a7afb

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 71 years; Vital status: Dead; Days to death: 270 days; Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 71.3 years (26,036 days); ISS stage: II; Days to last known disease status: 270 days; Days to last follow up: 270 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 270 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 6 days; Days to treatment end: 270 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 6 days; Days to treatment end: 227 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: Second line of therapy; Days to treatment start: 227 days; Days to treatment end: 270 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 270.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 0: M Protein 6.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.11 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 5.03 mg/dL; Immunoglobulin G 1.59 g/L; Immunoglobulin A 64 g/L; Immunoglobulin M 0.12 g/L; Beta 2 Microglobulin 4.92 µg/mL; Hemoglobin 4.77 mmol/L; Leukocytes 9 ×10⁹/L; Absolute Neutrophil 7.9 ×10⁹/L; Platelets 214 ×10⁹/L; Creatinine 76.9 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.68 mmol/L; Albumin 32 g/L; Total Protein 12 g/dL; Glucose 7.21 mmol/L.
- Day 77 (ECOG 0): M Protein 4.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.0065 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.38 mg/dL; Hemoglobin 5.46 mmol/L; Leukocytes 9.2 ×10⁹/L; Platelets 326 ×10⁹/L; Creatinine 57.5 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.25 mmol/L; Albumin 21 g/L; Total Protein 9.2 g/dL; Glucose 6.88 mmol/L.
- Day 196 (ECOG 1): M Protein 5.7 g/dL; Hemoglobin 5.64 mmol/L; Leukocytes 8.3 ×10⁹/L; Absolute Neutrophil 6.43 ×10⁹/L; Platelets 715 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.4 mmol/L; Albumin 27 g/L; Total Protein 10.4 g/dL; Glucose 8.36 mmol/L.

Other clinical attributes
- Day 0: Weight: 57 kg; Height: 151 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Lymphoma; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_1148_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 0 days.
- Sample MMRF_1148_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 0 days.
